Gene-level copy-number profile of tumor specimen C3N-03765-07 from CPTAC case C3N-03765, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 60.9 years (22,260 days).
Specimen C3N-03765-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dee53cf5-dd7f-417f-9ff2-0c939f112612.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03765-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/136ff0d2-e5f2-4099-bdc2-9172f59d5c5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 439; copy number 1: 5,793; copy number 2: 45,158; copy number 3: 7,014; copy number 4: 504; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:41,667,168–41,705,834, 1 gene (within-gene range 0–2): INHBA.
- chr9:19,926,094–26,118,408, 89 genes (broad region; genes not listed).
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
